Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RI, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RI-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
[REDACTED] (Age: [REDACTED] M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

History of anterior mediastinal mass.

year old male with anterior mediastinal mass.

Specimens Submitted:

1: Thymus (fs)

DIAGNOSIS:

1. Thymus; resection (fs):
- Thymoma, WHO 2004 type B2
- Tumor size: 3.5 x 3.0 x 2.5 cm
- Capsular invasion identified
- Surgical margins are negative for tumor
- No lymphovascular invasion identified
- Five benign lymph nodes (0/5)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Thymus", and consists of a 29.0 g, 7.5 x 4.5 x 3.8 cm portion of tan rubbery tissue with surrounding adipose tissue. The specimen is inked purple and sectioned to reveal a 3.5 x 3.0 x 2.5 cm tan-white, lobulated well-encapsulated soft mass. Sectioning the adipose tissue reveals a tan-pink rubbery possible lymph nodes ranging from 0.3 cm to 0.8 cm in

** Continued on next page **

ICD-O-3

Thymoma, type B2, malignant
808413

Site: Thymus
C37.9

FD 3/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT
Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

----- Page 2 of 2
greatest dimension. A representative section is submitted for frozen section control and TPS. The remaining mass is entirely submitted. All identified lymph nodes are entirely submitted.

Summary of sections:
FSCI_1-frozen section control
MA-mass
LN-(6) whole lymph nodes

Summary of Sections:
Part 1: Thymus (fs)

Blocks	Block Designation	PCs
1 FSC	1	
1 LN	6	
9 MA	9	

Intraoperative Consultation:
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Thymus (fs): Consistent with thymoma
Permanent Diagnosis: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Thymus (fs): Consistent with thymoma
Permanent Diagnosis: Same

** End of Report **

Criteria	AW 12/9/13	Yes	No

Source: NCI Genomic Data Commons file aa0e77d3-132d-4b74-9838-66fb376ae304 (TCGA-XM-A8RI.BF826305-1DA9-4899-9357-3CD69DD5A43A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).